Somatic mutation profile of tumor specimen 1dcde92b-2a59-427d-a7e6-48b476 (aliquot 1dcde92b-2a59-427d-a7e6-48b476_D6) from CPTAC case 04OV039, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 1dcde92b-2a59-427d-a7e6-48b476: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba3ebc3c-d7c1-46d0-b5fa-201dc364f188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d82ca4fc-d74c-4658-8920-897974 (Blood Derived Normal), aliquot d82ca4fc-d74c-4658-8920-897974_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c67f420-d2e7-48bb-ac69-49741cbb1dc0

The open-access MAF lists 78 somatic variants for this specimen: 59 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 11, Frame Shift Del 4, Splice Site 4, Intron 3, Nonsense Mutation 2, 3'UTR 2, 5'Flank 2, In Frame Del 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POLR3A | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 59/167 reads (35%) | catalogued as rs141659018, COSV104428130; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- RB1 | c.607+1G>A p.X203_splice | Splice Site (SNP) | VAF 34/65 reads (52%) | hotspot (GDC flag); catalogued as rs587776789, CD084205, CS951522, CS961676, CS961677, COSV57294293, COSV57310480; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 478/664 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL6A3 | c.3203C>T p.A1068V | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs907056422, COSV55112403; called by muse, mutect2, varscan2
- LLGL1 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 93/164 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV57496894; called by muse, mutect2, varscan2
- MAGI1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58329148; called by muse, mutect2, varscan2
- PTEN | c.497T>G p.V166G | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV64304104, COSV64306697, COSV64306841; called by muse, mutect2, varscan2
- RNF5 | c.46C>A p.R16S | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.726); catalogued as rs377192058; called by muse, mutect2, varscan2
- SLC44A4 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as rs755146927; called by muse, mutect2, varscan2
- AC097636.1 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ACRBP | c.263-32_263del p.X88_splice | Splice Site (DEL) | VAF 67/185 reads (36%) | called by mutect2, pindel, varscan2
- AMN | c.397_415del p.E133Tfs*60 | Frame Shift Del (DEL) | VAF 86/469 reads (18%) | called by mutect2, varscan2
- C11orf95 | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- C19orf12 | c.358G>C p.A120P (on ENST00000392278 / NM_001031726.3; = p.A109P on NM_031448.6) | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); called by muse, mutect2
- CACFD1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CHAT | c.368C>A p.T123N | Missense Mutation (SNP) | VAF 209/669 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2
- CLCN2 | c.1885_1897del p.R629Wfs*8 | Frame Shift Del (DEL) | VAF 112/554 reads (20%) | called by mutect2, pindel, varscan2
- CPA2 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, varscan2
- CSMD2 | c.3127G>T p.E1043* | Nonsense Mutation (SNP) | VAF 96/150 reads (64%) | called by muse, mutect2, varscan2
- CXCR2 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 112/328 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DACH1 | c.2093T>G p.F698C (on ENST00000619232 / NM_001366712.1; = p.F444C on NM_004392.6) | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DST | c.14974A>G p.N4992D (on ENST00000361203 / NM_001374722.1; = p.N2580D on NM_015548.5) | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- EIF2B1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 342/505 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- EPC2 | c.869G>T p.R290I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FGGY | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- IFT57 | c.500T>C p.I167T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- IP6K3 | c.879C>G p.H293Q | Missense Mutation (SNP) | VAF 124/434 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IRGC | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- IRX6 | c.54_78del p.S19Afs*75 | Frame Shift Del (DEL) | VAF 57/213 reads (27%) | called by mutect2, varscan2
- ITPRID1 | c.3114G>T p.K1038N | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KPRP | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 118/289 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- MALRD1 | c.5536A>G p.K1846E | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MLLT1 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MMP1 | c.274T>G p.C92G | Missense Mutation (SNP) | VAF 137/377 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NELFCD | c.1082A>G p.H361R (on ENST00000602795; = p.H343R on NM_198976.4) | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NGFR | c.430A>C p.T144P | Missense Mutation (SNP) | VAF 123/246 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- PALM | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 78/135 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIGT | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PRRT4 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS55 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 112/191 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PRX | c.2116C>A p.L706I | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ROBO4 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RRAS | c.344+2_344+35del p.X115_splice | Splice Site (DEL) | VAF 137/428 reads (32%) | called by mutect2, pindel, varscan2
- RYR2 | c.11409_11414del p.D3804_L3805del | In Frame Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- RYR3 | c.6311G>C p.S2104T | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD4B | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SDC3 | c.1055A>C p.K352T | Missense Mutation (SNP) | VAF 165/276 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SLC28A3 | c.362G>C p.C121S | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- SNX14 | c.1282A>G p.I428V (on ENST00000314673 / NM_001350535.1; = p.I384V on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SSPOP | n.3577_3587+34del | Splice Site (DEL) | VAF 54/181 reads (30%) | called by mutect2, pindel, varscan2
- TAF1 | c.4763A>G p.D1588G (on ENST00000373790 / NM_138923.4; = p.D1609G on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TANC2 | c.2513G>T p.G838V | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TBC1D17 | c.1035_1063del p.D345Efs*6 | Frame Shift Del (DEL) | VAF 56/182 reads (31%) | called by mutect2, pindel, varscan2
- TMEM239 | c.245G>T p.S82I (on ENST00000361033 / NM_001318207.1; = p.S39I on NM_001167670.3) | Missense Mutation (SNP) | VAF 146/381 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- UBA7 | c.2536G>C p.V846L | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- USP53 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- XAGE2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- ZNF462 | c.3425T>G p.V1142G | Missense Mutation (SNP) | VAF 96/319 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZSWIM1 | c.364A>C p.T122P | Missense Mutation (SNP) | VAF 124/448 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM6 | c.57A>G p.E19= | Silent (SNP) | VAF 38/62 reads (61%) | called by muse, varscan2
- ACTB | c.579C>A p.L193= | Silent (SNP) | VAF 24/500 reads (5%) | catalogued as rs759523049; called by muse, mutect2
- ATP4B | c.498G>A p.A166= | Silent (SNP) | VAF 152/286 reads (53%) | catalogued as rs780066459, COSV100089689; called by muse, mutect2, varscan2
- CCDC114 | c.1347G>A p.E449= | Silent (SNP) | VAF 52/172 reads (30%) | called by muse, mutect2, varscan2
- CECR2 | c.2418G>A p.L806= (on ENST00000342247 / NM_001290047.2; = p.L623= on NM_001290046.1) | Silent (SNP) | VAF 129/375 reads (34%) | catalogued as COSV99379334; called by muse, mutect2, varscan2
- GPR107 | c.1083C>A p.I361= | Silent (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- HMGXB4 | c.1110A>G p.G370= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as rs778144838; called by muse, mutect2, varscan2
- NDRG3 | c.351T>G p.A117= (on ENST00000349004 / NM_032013.4; = p.A105= on NM_022477.4) | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- NOL9 | c.987C>T p.C329= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs759991227; called by muse, mutect2, varscan2
- ZER1 | c.603G>A p.L201= | Silent (SNP) | VAF 161/405 reads (40%) | called by muse, mutect2, varscan2
- ZNFX1 | c.3042C>A p.A1014= | Silent (SNP) | VAF 51/202 reads (25%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1442C>G | RNA (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- CENPJ | c.*11G>A | 3'UTR (SNP) | VAF 33/104 reads (32%) | called by muse, mutect2, varscan2
- CUL7 | chr6:43053862 C>T | 5'Flank (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- DBNL | chr7:44040173 G>A | 5'Flank (SNP) | VAF 49/268 reads (18%) | called by muse, mutect2, varscan2
- LMOD1 | c.*1822_*1847delinsAG | 3'UTR (DEL) | VAF 78/186 reads (42%) | called by pindel, varscan2*
- MOG | c.730+76G>T | Intron (SNP) | VAF 78/329 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-1907C>A | Intron (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.-40+11287C>A | Intron (SNP) | VAF 47/142 reads (33%) | catalogued as rs1396973390; called by muse, mutect2, varscan2
